Gene-level copy-number profile of tumor specimen TCGA-CR-6473-01A from TCGA case TCGA-CR-6473, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; Tumor grade: G3; Age at diagnosis: 68.1 years (24,857 days).
Specimen TCGA-CR-6473-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.83e7a425-a813-4e7f-b913-3269ceb2a000.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6473-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/250847ed-822d-4c05-8097-cd736586ead8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,342; copy number 2: 42,963; copy number 3: 8,133; copy number 8: 379; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6473-01A-11D-1869-01): tumor purity 0.86, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 382 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:173,141,100–173,207,331, 3 genes, copy number 10: GOT2P2, AL022310.1, TNFSF4.
- chr20:17,941,597–34,825,651, 379 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,342. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
